MMRF case MMRF_1793 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a1ee433f-b49b-485a-a4ef-58d4c284663d

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.7 years (23,283 days); ISS stage: I; Days to last known disease status: 1,129 days (3.1 years); Days to last follow up: 1,129 days (3.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 42 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 105 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 64 days; Days to treatment end: 105 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 129 days; Days to treatment end: 129 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 196 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 0): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 28.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 33.3 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 4.23 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 8.7 g/dL; Glucose 6.6 mmol/L; C-Reactive Protein 0.5 mg/dL.
- Day 84 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Hemoglobin 5.95 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 1.95 mmol/L; Albumin 35 g/L; Total Protein 6.1 g/dL; Glucose 4.79 mmol/L.
- Day 162 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.15 mg/dL; Hemoglobin 7.87 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 288 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 7.1 g/dL; Glucose 7.54 mmol/L.
- Day 253 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.03 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 2.54 g/L; Immunoglobulin M 0.56 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 6.05 mmol/L.
- Day 338 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.64 mg/dL; Hemoglobin 6.82 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 7.2 g/dL; Glucose 5.67 mmol/L.
- Day 421 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.24 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 6.18 g/L; Immunoglobulin M 0.209 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 5.78 mmol/L.
- Day 534 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 5.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.69 mg/dL; Immunoglobulin G 9.89 g/L; Immunoglobulin A 6.03 g/L; Immunoglobulin M 0.235 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 6.49 mmol/L.
- Day 617 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 7.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.84 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 6.48 g/L; Immunoglobulin M 0.138 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 7.3 g/dL; Glucose 5.72 mmol/L.
- Day 701 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 4.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.55 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 5.45 g/L; Immunoglobulin M 0.116 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 5.39 mmol/L.
- Day 784 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 9.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.32 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 6.2 g/L; Immunoglobulin M 0.161 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 169 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.25 mmol/L; Albumin 45 g/L; Total Protein 8.3 g/dL; Glucose 5.5 mmol/L.
- Day 849 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 6.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.53 mg/dL; Immunoglobulin G 9.76 g/L; Immunoglobulin A 5.57 g/L; Immunoglobulin M 0.119 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 5.94 mmol/L.
- Day 939 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 7.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.41 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 6.99 g/L; Immunoglobulin M 0.139 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 7.1 g/dL; Glucose 6.05 mmol/L.
- Day 1,037 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 8.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.95 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 8.56 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 134 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 7.4 g/dL; Glucose 5.89 mmol/L.
- Day 1,129 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 7.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.3 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 13.1 g/L; Immunoglobulin M 0.343 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 8.1 g/dL; Glucose 5.94 mmol/L.

Other clinical attributes
- Day -20: Weight: 58 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1793_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_1793_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
